Somatic mutation profile of tumor specimen TCGA-YU-A90W-01A (aliquot TCGA-YU-A90W-01A-11D-A435-10) from TCGA case TCGA-YU-A90W, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 45.2 years (16,497 days).
Specimen TCGA-YU-A90W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77193e2d-56e8-42fb-865c-6d4a7b510d7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YU-A90W-10A (Blood Derived Normal), aliquot TCGA-YU-A90W-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b33b9ca-cf3e-4e94-9e1e-4bc293439fd6

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DST | c.18545C>T p.A6182V (on ENST00000361203 / NM_001374722.1; = p.A3879V on NM_015548.5) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.839); catalogued as rs1361361436; called by muse, mutect2
- ERICH1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 89/428 reads (21%) | catalogued as rs150434775; called by muse, mutect2, varscan2
- LMNTD2 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs776944817; called by muse, mutect2, varscan2
- PRDM7 | c.1466G>C p.G489A | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); catalogued as COSV57986417; called by muse, mutect2, varscan2
- ZNF277 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); catalogued as rs762709994; called by muse, mutect2, varscan2
- ATP2A1 | c.2862+2T>A p.X954_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- CCSER2 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CDK12 | c.1767_1770del p.H589Qfs*20 | Frame Shift Del (DEL) | VAF 80/252 reads (32%) | called by pindel, varscan2
- CHRDL1 | c.1112A>G p.H371R (on ENST00000372045; = p.H377R on NM_145234.4) | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- COBL | c.1957G>T p.G653C | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DCDC1 | c.3470G>T p.S1157I (on ENST00000597505 / NM_001367979.1; = p.S264I on NM_020869.3) | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- DNM2 | c.2435G>T p.R812L (on ENST00000355667 / NM_001005360.3; = p.R808L on NM_004945.3) | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- FOXD4 | c.1219C>G p.L407V | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); called by muse, mutect2
- KLK11 | c.649A>G p.T217A (on ENST00000594768 / NM_144947.3; = p.T185A on NM_006853.3) | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- KRT19 | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PARP14 | c.3014A>G p.K1005R | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP12 | c.673_674del p.L225Vfs*3 | Frame Shift Del (DEL) | VAF 32/214 reads (15%) | called by pindel, varscan2
- ZNF85 | c.832A>T p.I278L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- FKBP4 | c.594G>C p.L198= | Silent (SNP) | VAF 19/106 reads (18%) | called by muse, mutect2, varscan2
- GPR39 | c.168G>A p.Q56= | Silent (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- PITX1 | c.879G>C p.S293= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs61751190; called by muse, mutect2, varscan2
- RABEP1 | c.105T>C p.L35= | Silent (SNP) | VAF 52/361 reads (14%) | called by muse, mutect2, varscan2
- TPR | c.7041G>A p.V2347= | Silent (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- LRRC37BP1 | n.1242_1250del | RNA (DEL) | VAF 18/148 reads (12%) | catalogued as rs772085726; called by mutect2, varscan2
